Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6YX, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6YX-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

ICD-O-3
Fibromyxosarcoma 8811/3
Site @ Thigh NOS C49.2
QW 8/9/13

....

Clinical Diagnosis & History:

[REDACTED] with right thigh sarcoma.

Specimens Submitted:

1: SP: Radical resection of right posterior thigh with sartorius, biceps, bacillus and femoral muscle

DIAGNOSIS:

- 1) SOFT TISSUE; RIGHT POSTERIOR THIGH, RADICAL RESECTION:
- HIGH GRADE MYXOFIBROSARCOMA.
- TUMOR SIZE: 9.5 x 8 x 7 CM.
- TUMOR INVOLVES SUBCUTANEOUS TISSUE AND DERMIS.
- FOCAL AREAS OF NECROSIS ARE IDENTIFIED.
- THE RESECTION MARGINS ARE FREE OF TUMOR. THE CLOSEST IS THE MEDIAL MARGIN, 0.25 CM MICROSCOPIC CLEARANCE.
- PORTION OF UNINVOLVED SKELETAL MUSCLE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh, it is labeled "radical resection of right posterior thigh, with sartorius biceps, bacillus and femoral muscles". It consists of a portion of skin with underlying subcutaneous tissue and muscle. The entire specimen measures 25 x 13 x 8.5 cm. The overlying skin measures 17 x 8 cm and contains a centrally located bulging area. The specimen is oriented with a short suture for superior, and a long suture for lateral, and is inked as follows: superior red, lateral yellow, inferior green, medial blue and deep margin is inked in black. Sectioning of the specimen reveals a multilobulated firm mass which abuts the skin superiorly

** Continued on next page **

[page 2 of 2]
----- Page 2 of 2
and is grossly present at 0.5 cm from the lateral and medial margins. The mass measures 9.5 x 8 x 7cm and appears to push but not infiltrate the underlying skeletal muscle. Portions of the specimens are submitted for TPS and the specimen is photographed. Representative sections are submitted.

Summary of sections:

T tumor
SM superior margin.
MM medial margin
LM lateral margin
DM deep margin.
TM tumor with muscle.
TS -- tumor with skin
IM inferior margin

Summary of Sections:

Part 1: SP: Radical resection of right posterior thigh with sartorius, biceps, gracilis and femoral muscle

Block	Sect.	Site	PCs
1		DM	1
1		IM	1
1		LM	1
1		MM	1
1		SM	1
8		T	8
1		TM	1
3		TS	3

** End of Report **

Source: NCI Genomic Data Commons file f8f57bea-f9c1-4abc-8968-df18bd825f56 (TCGA-DX-A6YX.9F080172-553B-4FEA-BD2D-043C7DE9245F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).